Somatic mutation profile of tumor specimen TCGA-38-4629-01A (aliquot TCGA-38-4629-01A-02D-1265-08) from TCGA case TCGA-38-4629, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.7 years (25,104 days).
Specimen TCGA-38-4629-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17aa2bf6-e83b-4a21-895b-af624c4da749.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-38-4629-11A (Solid Tissue Normal), aliquot TCGA-38-4629-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/470b8e24-fe52-48ef-a2ff-dccc721d7a8b

The open-access MAF lists 301 somatic variants for this specimen: 227 protein-altering or splice-affecting, 64 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 191, Silent 64, Frame Shift Del 11, Nonsense Mutation 11, Splice Site 5, Intron 5, Frame Shift Ins 3, In Frame Del 2, RNA 2, 3'UTR 2, Splice Region 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.9005T>G p.L3002R | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71284052, COSV71284585; called by muse, mutect2
- ABCB5 | c.3262T>C p.W1088R (on ENST00000404938 / NM_001163941.2; = p.W643R on NM_178559.6) | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51703911; called by muse, varscan2
- ABCG5 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs768541576, COSV53209678; called by muse, mutect2, varscan2
- ACSS3 | c.1042C>A p.H348N | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54085991; called by muse, mutect2, varscan2
- ACTL9 | c.1071G>C p.E357D | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as COSV61004907; called by muse, mutect2, varscan2
- ADAM2 | c.2063C>T p.P688L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV55859336; called by muse, mutect2, varscan2
- ADGRB2 | c.4130G>T p.R1377L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.212); catalogued as COSV57071613; called by muse, mutect2
- ADGRE2 | c.656G>C p.G219A | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV100215904; called by muse, mutect2, varscan2
- AFF2 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV53978708; called by muse, mutect2, varscan2
- AHNAK | c.4670C>G p.A1557G | Missense Mutation (SNP) | VAF 69/276 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57205212; called by muse, mutect2, varscan2
- AKAP9 | c.7097A>G p.K2366R (on ENST00000359028; = p.K2342R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/186 reads (73%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.592); catalogued as COSV62339878; called by muse, mutect2, varscan2
- AMER3 | c.1981G>A p.G661S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV58465382; called by muse, mutect2, varscan2
- ANK2 | c.8522G>T p.S2841I | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV52148515; called by muse, mutect2, varscan2
- ANK2 | c.9694G>C p.D3232H | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV52148526; called by muse, mutect2, varscan2
- ANKK1 | c.693G>T p.M231I | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.285); catalogued as COSV100392793, COSV58273354; called by muse, mutect2, varscan2
- ANKRD30A | c.2727C>A p.F909L (on ENST00000611781; = p.F853L on NM_052997.2) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as COSV100653280, COSV64605715; called by muse, mutect2
- APPL2 | c.1170G>C p.L390F | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV51588518, COSV51589971; called by muse, mutect2, varscan2
- AQR | c.262A>G p.K88E | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV50029959; called by muse, mutect2, varscan2
- ARHGEF16 | c.1248G>A p.M416I | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); catalogued as COSV65681433; called by muse, mutect2, varscan2
- ARID1B | c.3238G>C p.V1080L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51650679, COSV51682107; called by muse, mutect2, varscan2
- ASTN1 | c.3643C>A p.P1215T | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100707693, COSV62492095; called by muse, mutect2, varscan2
- ATP12A | c.3086C>A p.P1029H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV54513038; called by muse, mutect2, varscan2
- ATP2B1 | c.2624G>T p.C875F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53804485; called by muse, mutect2, varscan2
- BAIAP3 | c.1584C>A p.S528R | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.189); catalogued as COSV60977643; called by muse, mutect2, varscan2
- C6 | c.614G>T p.R205I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54706107, COSV99667965; called by muse, mutect2, varscan2
- CACNA1C | c.1503G>T p.K501N | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV59699720; called by muse, mutect2, varscan2
- CACNG5 | c.175T>A p.W59R | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50054861; called by muse, varscan2
- CCDC88B | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); catalogued as COSV57265110; called by muse, mutect2, varscan2
- CHERP | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.459); catalogued as COSV52222645; called by muse, mutect2
- CLCN3 | c.580del p.A194Qfs*3 | Frame Shift Del (DEL) | VAF 21/155 reads (14%) | catalogued as COSV100641654; called by mutect2, pindel, varscan2
- CNTNAP4 | c.2133C>A p.Y711* | Nonsense Mutation (SNP) | VAF 32/86 reads (37%) | catalogued as COSV56667421; called by muse, mutect2, varscan2
- COL11A1 | c.1439C>A p.P480Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV62174553; called by muse, mutect2, varscan2
- COX18 | c.443A>T p.Y148F | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.018); catalogued as COSV55719846; called by muse, mutect2, varscan2
- CPLANE1 | c.9493A>C p.T3165P | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57053762; called by muse, mutect2, varscan2
- CYB5R4 | c.1346G>T p.R449I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63750245; called by muse, mutect2, varscan2
- CYLC2 | c.795G>C p.K265N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV100872578, COSV66336368; called by mutect2, varscan2
- CYYR1 | c.274A>T p.R92W | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV54828230; called by muse, mutect2, varscan2
- DAB1 | c.917C>A p.P306Q (on ENST00000371231; = p.P273Q on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV64690541; called by muse, mutect2, varscan2
- DEPDC7 | c.139C>G p.Q47E (on ENST00000241051 / NM_001077242.2; = p.Q38E on NM_139160.2) | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV53805961; called by muse, mutect2, varscan2
- DNAH11 | c.7585G>T p.E2529* | Nonsense Mutation (SNP) | VAF 21/122 reads (17%) | catalogued as COSV60942339; called by muse, mutect2, varscan2
- DROSHA | c.3462G>A p.M1154I | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV60773163; called by muse, varscan2
- E4F1 | c.245G>T p.C82F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1276368344, COSV100066258, COSV57037813; called by muse, mutect2, varscan2
- EDC4 | c.1913G>A p.S638N | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100197369, COSV59302078; called by muse, mutect2, varscan2
- EGFR | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as COSV51776247; called by muse, mutect2, varscan2
- ELFN2 | c.382del p.R128Afs*15 | Frame Shift Del (DEL) | VAF 31/130 reads (24%) | catalogued as COSV68746121; called by mutect2, pindel, varscan2
- EMILIN1 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1354099607, COSV53153507; called by muse, mutect2, varscan2
- EPX | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 42/432 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as rs1167190958, COSV56595226; called by muse, mutect2
- ERBB2 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 42/691 reads (6%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.964); catalogued as rs776515406, COSV54064519; called by muse, mutect2
- ETS2 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV62872380; called by muse, mutect2, varscan2
- FASN | c.2355G>A p.M785I | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV60750343, COSV60751082; called by muse, mutect2, varscan2
- FAT4 | c.11513T>A p.I3838N | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV58673573; called by muse, mutect2, varscan2
- FBXO24 | c.642del p.T215Pfs*24 (on ENST00000241071 / NM_033506.3; = p.T253Pfs*24 on NM_012172.5) | Frame Shift Del (DEL) | VAF 29/63 reads (46%) | catalogued as COSV99575386; called by mutect2, pindel, varscan2
- FMN2 | c.240C>G p.I80M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60419254; called by muse, mutect2, varscan2
- FOXI1 | c.769C>A p.P257T | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV60388106; called by muse, mutect2, varscan2
- GABRB2 | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as COSV50903874; called by muse, mutect2, varscan2
- GAR1 | c.249C>G p.D83E | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.779); catalogued as COSV56993004; called by muse, mutect2, varscan2
- GLB1L2 | c.558G>A p.Q186= | Splice Region (SNP) | VAF 21/315 reads (7%) | catalogued as COSV100335009, COSV60277630; called by muse, mutect2
- GLDC | c.1059-1G>T p.X353_splice | Splice Site (SNP) | VAF 22/59 reads (37%) | catalogued as COSV58676910; called by muse, mutect2, varscan2
- GMPPA | c.1183G>C p.A395P | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV58006193, COSV58007032; called by muse, mutect2, varscan2
- GPR158 | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1396714266, COSV66266128; called by muse, mutect2, varscan2
- GPR4 | c.29A>C p.H10P | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV59916296; called by muse, mutect2, varscan2
- GREB1 | c.623G>A p.C208Y | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV52181815, COSV52187793; called by muse, mutect2
- GRIA2 | c.2491G>A p.A831T | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52383728; called by muse, mutect2, varscan2
- GRIA4 | c.593T>C p.L198P | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56884151; called by muse, mutect2, varscan2
- GRM1 | c.2407C>T p.P803S | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51110897; called by muse, mutect2, varscan2
- GTF3C5 | c.1338G>T p.E446D | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV100565365; called by muse, mutect2, varscan2
- HCN4 | c.1659C>A p.D553E | Missense Mutation (SNP) | VAF 81/238 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV56081715; called by muse, varscan2
- HEATR1 | c.3969C>G p.I1323M | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63979938, COSV63982852; called by muse, mutect2, varscan2
- HERC2 | c.6267G>T p.R2089S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.916); catalogued as rs1373564734, COSV55310040; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.698G>C p.G233A (on ENST00000354667 / NM_031243.3; = p.G221A on NM_002137.4) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV61158199; called by muse, mutect2, varscan2
- HOXA5 | c.800C>A p.A267D | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs769142318, COSV56072394; called by muse, mutect2
- HRNR | c.1468G>A p.G490S | Missense Mutation (SNP) | VAF 66/410 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs138042599; called by muse, varscan2
- IGF1R | c.1997-1G>T p.X666_splice | Splice Site (SNP) | VAF 29/71 reads (41%) | catalogued as COSV51271320; called by muse, mutect2, varscan2
- IGF2BP1 | c.1354C>G p.R452G | Missense Mutation (SNP) | VAF 107/372 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51729521, COSV51730080; called by muse, mutect2, varscan2
- IGLV8-61 | c.224A>G p.Y75C | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as rs529453163, COSV66502557; called by muse, mutect2, varscan2
- INSL6 | c.104G>T p.R35M | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101068460, COSV101068548; called by muse, mutect2, varscan2
- INTS12 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 64/204 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV60861711; called by muse, mutect2, varscan2
- IQCH | c.2378C>T p.S793L | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60049669; called by muse, mutect2, varscan2
- IRS4 | c.1619C>A p.S540* | Nonsense Mutation (SNP) | VAF 89/203 reads (44%) | catalogued as COSV64532813; called by muse, mutect2, varscan2
- JADE3 | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV54464642; called by muse, mutect2, varscan2
- KCNH4 | c.3052T>A p.*1018Rext*53 | Nonstop Mutation (SNP) | VAF 20/88 reads (23%) | catalogued as COSV52915753; called by muse, mutect2, varscan2
- KLF17 | c.1001T>A p.M334K | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as COSV64855949; called by muse, mutect2, varscan2
- KLF6 | c.801G>A p.R267= | Splice Region (SNP) | VAF 13/78 reads (17%) | catalogued as COSV51493848; called by muse, mutect2, varscan2
- KLHL4 | c.490C>A p.H164N | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV64139545; called by muse, varscan2
- KRT14 | c.500A>G p.K167R | Missense Mutation (SNP) | VAF 81/316 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as COSV51420396; called by muse, mutect2, varscan2
- KRTAP10-11 | c.734G>C p.C245S | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58177223; called by muse, mutect2, varscan2
- KRTAP13-2 | c.380T>A p.V127D | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV67761886; called by muse, mutect2, varscan2
- LRRC74A | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV53608087; called by muse, mutect2, varscan2
- MANEA | c.95A>G p.N32S | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV100721492; called by muse, mutect2, varscan2
- MAST4 | c.1433G>T p.R478L (on ENST00000403625 / NM_001164664.2; = p.R289L on NM_015183.3) | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55117320; called by muse, mutect2, varscan2
- MEFV | c.1013T>G p.V338G | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV54818934; called by muse, mutect2, varscan2
- MIA2 | c.479A>G p.Q160R | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as COSV54482234; called by muse, mutect2, varscan2
- MOCS3 | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.557); catalogued as rs1431753709, COSV54865668; called by muse, mutect2, varscan2
- MPP2 | c.893A>G p.H298R (on ENST00000461854 / NM_001278372.2; = p.H274R on NM_005374.5) | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as COSV52233345; called by muse, mutect2, varscan2
- MROH2B | c.4057C>A p.L1353M | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV68181653; called by muse, mutect2, varscan2
- MYH6 | c.3973G>A p.G1325S | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV62448253; called by muse, mutect2, varscan2
- MYOCD | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV58498194; called by muse, mutect2, varscan2
- MYOM3 | c.2885G>T p.G962V | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1361166121, COSV58390509; called by muse, mutect2, varscan2
- NBEA | c.7091C>T p.T2364I | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV59763538; called by muse, mutect2
- NCAPH2 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1351695729, COSV100238538, COSV55366702; called by muse, mutect2, varscan2
- NCOA6 | c.3188C>T p.P1063L | Missense Mutation (SNP) | VAF 88/326 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs752025910, COSV62861671; called by muse, mutect2, varscan2
- NDN | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.672); catalogued as COSV100086393, COSV59361564; called by muse, mutect2, varscan2
- NDNF | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV65632728; called by muse, mutect2, varscan2
- NECAB1 | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766990025, COSV70237260; called by muse, mutect2, varscan2
- NEURL4 | c.4300C>T p.R1434* | Nonsense Mutation (SNP) | VAF 24/196 reads (12%) | catalogued as rs777946838, COSV59747468; called by muse, mutect2, varscan2
- NF1 | c.3624G>T p.L1208F | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV62194703; called by muse, mutect2, varscan2
- NFATC4 | c.859C>A p.R287S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs755808600, COSV51597241; called by muse, mutect2, varscan2
- NID2 | c.2629T>G p.C877G | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV53493510; called by muse, mutect2, varscan2
- NOC4L | c.1357G>T p.A453S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs755773641, COSV100400074; called by muse, mutect2, varscan2
- NOTCH4 | c.1131C>A p.F377L | Missense Mutation (SNP) | VAF 101/268 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV66679065, COSV66680815; called by muse, mutect2, varscan2
- NRXN2 | c.2044G>A p.V682I | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1056113277, COSV55448163; called by muse, mutect2, varscan2
- NXPE4 | c.1579C>A p.P527T (on ENST00000375478 / NM_001077639.2; = p.P243T on NM_017678.3) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV64943457; called by muse, mutect2, varscan2
- OCM2 | c.23G>T p.S8I | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV57535160, COSV99990899; called by muse, mutect2, varscan2
- OR1S2 | c.508C>A p.L170I | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV56918525; called by muse, varscan2
- OR2L8 | c.391T>A p.Y131N | Missense Mutation (SNP) | VAF 50/312 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV61725757; called by muse, mutect2, varscan2
- OR2T3 | c.895A>C p.N299H | Missense Mutation (SNP) | VAF 66/427 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV62081885; called by muse, mutect2, varscan2
- OR2T8 | c.78C>A p.F26L | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV60661743; called by muse, mutect2, varscan2
- OR4C13 | c.179T>C p.F60S | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.458); catalogued as COSV73648652; called by muse, mutect2, varscan2
- OR4M1 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 89/506 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV60059765, COSV60060322, COSV60060528; called by muse, mutect2, varscan2
- OR4S2 | c.362A>T p.Y121F | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56746038; called by muse, mutect2, varscan2
- OR5A2 | c.443G>C p.G148A | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.217); catalogued as COSV100119665, COSV57390463; called by muse, mutect2, varscan2
- OR5B3 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as COSV58676486; called by muse, mutect2, varscan2
- OR6K6 | c.482C>A p.P161Q (on ENST00000368144; = p.P137Q on NM_001005184.1) | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as COSV63743680; called by muse, mutect2, varscan2
- OR8H2 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 114/528 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57943366; called by muse, mutect2, varscan2
- OR8H2 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57943201, COSV57943380; called by muse, mutect2, varscan2
- OTOGL | c.6131C>G p.P2044R (on ENST00000547103; = p.P2035R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.263); catalogued as COSV100087101; called by muse, mutect2, varscan2
- OTUD7B | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV64915308; called by muse, mutect2, varscan2
- PBRM1 | c.1565G>T p.R522L | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV56263407; called by muse, mutect2, varscan2
- PCDH10 | c.2047G>C p.V683L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as COSV52088384, COSV52104605; called by muse, mutect2
- PCDH7 | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62336945; called by muse, mutect2, varscan2
- PCDH9 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60531662; called by muse, mutect2, varscan2
- PCDHGA1 | c.2342G>T p.S781I | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); catalogued as COSV65295197; called by muse, mutect2, varscan2
- PCDHGA8 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.014); catalogued as rs1034199960, COSV53906907; called by muse, mutect2, varscan2
- PDPR | c.1191G>T p.K397N | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV55349584, COSV55353592; called by muse, mutect2, varscan2
- PEG3 | c.4043C>T p.T1348I | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.433); catalogued as rs927599827, COSV55626530; called by muse, mutect2, varscan2
- PFKFB3 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 51/206 reads (25%) | PolyPhen benign (0.345); catalogued as COSV57987147, COSV57991710; called by muse, mutect2, varscan2
- PHF3 | c.3826C>A p.P1276T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50313901; called by muse, mutect2, varscan2
- PKHD1 | c.9828A>T p.Q3276H | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV61862947, COSV61897206, COSV61898567; called by muse, mutect2, varscan2
- PKHD1 | c.1599T>A p.H533Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV61862959; called by muse, mutect2, varscan2
- PLEC | c.6934G>A p.E2312K (on ENST00000322810 / NM_201380.4; = p.E2202K on NM_000445.5) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs375723079; ClinVar: uncertain significance; called by muse, mutect2
- PLXDC2 | c.177C>A p.H59Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV65912485, COSV65914668; called by muse, mutect2, varscan2
- POLR1A | c.4850C>T p.A1617V | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs766483569, COSV55689748; called by muse, mutect2
- POLR2B | c.1327G>T p.G443C | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58898821; called by muse, mutect2, varscan2
- POLR3A | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64930346; called by muse, mutect2, varscan2
- POT1 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs797045168, CM1412277, COSV62928287; ClinVar: risk factor / uncertain significance; called by muse, mutect2, varscan2
- PPP2R5E | c.641G>T p.R214I | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV61740764; called by muse, mutect2, varscan2
- PROS1 | c.1871-2A>T p.X624_splice | Splice Site (SNP) | VAF 15/49 reads (31%) | catalogued as COSV101260386; called by muse, mutect2, varscan2
- PRPF3 | c.1854G>T p.E618D | Missense Mutation (SNP) | VAF 57/294 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV61394034; called by muse, mutect2, varscan2
- PTPRD | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 56/161 reads (35%) | catalogued as COSV100644231, COSV61931321; called by muse, mutect2, varscan2
- PTPRD | c.1092G>T p.E364D | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0.009); catalogued as COSV100644235; called by muse, mutect2, varscan2
- PYGM | c.1768C>A p.R590S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV51215084; called by muse, mutect2, varscan2
- RALGAPA1 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV51877568; called by muse, mutect2, varscan2
- REEP1 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.031); catalogued as COSV51255886; called by muse, mutect2, varscan2
- REV1 | c.1325A>T p.K442I | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51482331; called by muse, mutect2
- RFX4 | c.1267G>A p.V423M (on ENST00000392842 / NM_213594.3; = p.V329M on NM_032491.6) | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as rs753044935, COSV57572833; called by muse, mutect2, varscan2
- RIMS1 | c.217G>C p.A73P | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV53441798; called by muse, mutect2
- RNF43 | c.687+1G>C p.X229_splice | Splice Site (SNP) | VAF 34/157 reads (22%) | catalogued as COSV68457097, COSV68458877; called by muse, mutect2, varscan2
- RNPEP | c.1150G>T p.D384Y | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV55239381; called by muse, mutect2, varscan2
- ROBO3 | c.1217G>T p.R406I | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV67299570; called by muse, mutect2, varscan2
- RPS6KB1 | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV56675572; called by muse, mutect2, varscan2
- RSBN1 | c.1936-1G>A p.X646_splice | Splice Site (SNP) | VAF 25/58 reads (43%) | catalogued as COSV54734787; called by muse, varscan2
- RUBCNL | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV59785816; called by muse, mutect2, varscan2
- SATB2 | c.1735G>T p.V579L | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53479263; called by muse, mutect2, varscan2
- SCN2A | c.5494G>T p.A1832S | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV99331078; called by muse, varscan2
- SECISBP2L | c.1711C>T p.R571* (on ENST00000559471 / NM_001193489.2; = p.R526* on NM_014701.4) | Nonsense Mutation (SNP) | VAF 9/121 reads (7%) | catalogued as rs927521450, COSV55933000; called by muse, mutect2
- SENP7 | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV58608570, COSV58616756; called by muse, mutect2, varscan2
- SH3BP5L | c.178A>T p.I60L | Missense Mutation (SNP) | VAF 79/419 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV63538809; called by muse, mutect2, varscan2
- SIPA1L1 | c.4925G>C p.G1642A | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as rs1449623843, COSV62168795, COSV62173396; called by muse, mutect2, varscan2
- SLC25A18 | c.106C>A p.L36M | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV59407768; called by muse, mutect2, varscan2
- SLC26A2 | c.1279_1281del p.I427del | In Frame Del (DEL) | VAF 14/72 reads (19%) | catalogued as rs1174821568; called by pindel, varscan2
- SLIT1 | c.3398G>T p.G1133V | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.058); catalogued as COSV56583700; called by muse, mutect2, varscan2
- SLITRK1 | c.29C>A p.T10K | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as COSV65674478; called by muse, mutect2, varscan2
- SMARCC2 | c.2482A>C p.K828Q | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as COSV57214712; called by muse, mutect2, varscan2
- SPAG16 | c.1315G>T p.V439L | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV59074739; called by muse, mutect2, varscan2
- SPINK5 | c.1771C>G p.L591V | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.842); catalogued as rs1347502043, COSV56249629; called by muse, mutect2, varscan2
- SV2A | c.1260G>T p.W420C | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV64964329; called by muse, mutect2, varscan2
- TAF4B | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52301532; called by muse, mutect2, varscan2
- TBC1D31 | c.1819G>A p.V607I | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.802); catalogued as COSV54864087; called by muse, mutect2, varscan2
- TBX3 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985381779, COSV57469567; called by muse, mutect2, varscan2
- TDRD7 | c.193A>T p.S65C | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV62428528; called by muse, mutect2, varscan2
- TECTA | c.3082A>T p.S1028C | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as COSV50689968; called by muse, mutect2, varscan2
- TEP1 | c.1935G>A p.W645* | Nonsense Mutation (SNP) | VAF 46/164 reads (28%) | catalogued as COSV52988752; called by muse, mutect2, varscan2
- TKTL2 | c.1207C>A p.Q403K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.986); catalogued as COSV54917586; called by muse, mutect2, varscan2
- TLL1 | c.2491C>A p.H831N | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.308); catalogued as COSV50263048; called by muse, mutect2, varscan2
- TLL2 | c.1771C>A p.R591S | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.563); catalogued as COSV63571026; called by muse, mutect2, varscan2
- TLN2 | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100168698; called by muse, varscan2
- TM6SF1 | c.489T>A p.Y163* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as COSV51943242; called by muse, mutect2, varscan2
- TMED8 | c.975C>G p.S325R | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV53625422; called by muse, mutect2
- TMEM214 | c.724C>G p.L242V | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV53191910; called by muse, mutect2, varscan2
- TNFRSF12A | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1172974507, COSV50188234; called by muse, mutect2, varscan2
- TOX | c.378G>T p.Q126H | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV63843052; called by muse, mutect2, varscan2
- TP53 | c.602dup p.L201Ffs*8 | Frame Shift Ins (INS) | VAF 22/64 reads (34%) | catalogued as COSV53023337; called by mutect2, pindel, varscan2
- TRIM29 | c.1208A>T p.E403V | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV59279220, COSV59281679; called by muse, mutect2, varscan2
- TRIM48 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as COSV70160937; called by muse, mutect2
- TRPM1 | c.3929A>G p.K1310R | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV56631169; called by muse, mutect2, varscan2
- TRPM1 | c.987T>G p.F329L | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV56631183; called by muse, mutect2, varscan2
- UBQLN3 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as rs374667845; called by muse, mutect2, varscan2
- UPF2 | c.3426T>G p.I1142M | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62658684; called by muse, mutect2, varscan2
- USP29 | c.885C>A p.Y295* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as rs759034803, COSV54140409; called by muse, mutect2, varscan2
- USP4 | c.1965C>A p.S655R | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.288); catalogued as COSV55535182; called by muse, mutect2, varscan2
- VPS13A | c.6083T>C p.L2028S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62425783; called by muse, mutect2, varscan2
- WDR35 | c.2966A>T p.Q989L (on ENST00000345530 / NM_001006657.2; = p.Q978L on NM_020779.4) | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55600784; called by muse, mutect2, varscan2
- WFDC10B | c.193T>A p.C65S | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100225064; called by muse, mutect2, varscan2
- WSCD2 | c.516del p.L173Wfs*18 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as COSV54587083, COSV54587557; called by mutect2, pindel, varscan2
- XPO5 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.178); catalogued as COSV54827754; called by muse, mutect2, varscan2
- YIPF5 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as COSV50822921; called by muse, mutect2, varscan2
- ZFP64 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1362629614, COSV53800932, COSV99402269; called by muse, mutect2, varscan2
- ZNF423 | c.2942C>T p.T981M (on ENST00000563137 / NM_001379286.1; = p.T973M on NM_015069.4) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs773947241, COSV52178092; called by muse, mutect2, varscan2
- ZNF521 | c.793A>T p.I265F | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs1424892848, COSV64123087; called by muse, mutect2, varscan2
- ZNF572 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV60001312; called by muse, mutect2, varscan2
- ZNF578 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.103); catalogued as COSV101405052, COSV69735858; called by mutect2, varscan2
- ZNF624 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100257189; called by muse, mutect2, varscan2
- ZNF668 | c.1543del p.Q515Sfs*14 | Frame Shift Del (DEL) | VAF 28/144 reads (19%) | catalogued as rs760397907; called by mutect2, varscan2
- ZNF669 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.025); catalogued as COSV58537010, COSV58537384; called by muse, mutect2
- ZSWIM8 | c.3823C>T p.R1275C (on ENST00000605216 / NM_001242487.2; = p.R1280C on NM_015037.3) | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55213016; called by muse, mutect2
- BIN2 | c.1114_1138del p.G372Lfs*8 | Frame Shift Del (DEL) | VAF 27/115 reads (23%) | called by mutect2, pindel, varscan2
- CLCN3 | c.575C>A p.T192K | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by mutect2, varscan2
- DYRK1A | c.2010del p.S671Lfs*32 | Frame Shift Del (DEL) | VAF 28/191 reads (15%) | called by mutect2, pindel, varscan2
- EXOC4 | c.1082dup p.Y362Ifs*20 | Frame Shift Ins (INS) | VAF 29/128 reads (23%) | called by mutect2, pindel, varscan2
- IGHV2-26 | c.322C>A p.P108T | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- KCTD3 | c.1311_1325del p.C438_N442del | In Frame Del (DEL) | VAF 7/64 reads (11%) | called by mutect2, pindel, varscan2
- MYO18B | c.5038del p.E1680Kfs*7 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- OR2V2 | c.287_288del p.V96Gfs*16 | Frame Shift Del (DEL) | VAF 69/264 reads (26%) | called by pindel, varscan2
- OR51S1 | c.655del p.L219Cfs*9 | Frame Shift Del (DEL) | VAF 31/146 reads (21%) | called by mutect2, pindel, varscan2
- POLR2A | c.5104A>T p.T1702S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- SPRR4 | c.92del p.P31Lfs*79 | Frame Shift Del (DEL) | VAF 67/232 reads (29%) | called by mutect2, pindel, varscan2
- TTN | c.36069dup p.G12024Wfs*6 (on ENST00000591111; = p.G4600Wfs*6 on NM_003319.4) | Frame Shift Ins (INS) | VAF 19/80 reads (24%) | called by mutect2, pindel, varscan2
- ABCB5 | c.3111C>A p.S1037= (on ENST00000404938 / NM_001163941.2; = p.S592= on NM_178559.6) | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as COSV51703887; called by muse, mutect2, varscan2
- ADGRL3 | c.1686C>T p.L562= (on ENST00000506720 / NM_001322402.2; = p.L494= on NM_015236.6) | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs777306058, COSV72229580; called by muse, mutect2, varscan2
- AMER3 | c.921C>T p.T307= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as rs186201647, COSV58465373; called by muse, mutect2, varscan2
- AMPH | c.561A>G p.L187= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV57734422; called by muse, mutect2, varscan2
- APOBR | c.141G>T p.L47= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100112431; called by muse, mutect2
- ATP12A | c.978G>T p.V326= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV54513008; called by muse, mutect2, varscan2
- BSN | c.5190C>G p.T1730= | Silent (SNP) | VAF 126/359 reads (35%) | catalogued as COSV56513705; called by muse, mutect2, varscan2
- C16orf90 | c.150C>T p.S50= (on ENST00000399645 / NM_001353385.2; = p.S41= on NM_001080524.2) | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV101290956; called by muse, mutect2, varscan2
- CACNA1C | c.5322C>A p.A1774= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV59699744; called by muse, mutect2
- CAPN5 | c.1989G>A p.L663= (on ENST00000456580; = p.L623= on NM_004055.5) | Silent (SNP) | VAF 32/150 reads (21%) | catalogued as COSV53685856; called by muse, mutect2, varscan2
- CCDC61 | c.213G>T p.L71= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV54427834; called by muse, mutect2, varscan2
- CDH5 | c.1554G>A p.L518= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV58516188, COSV58516456; called by muse, mutect2, varscan2
- CHAT | c.1767T>A p.A589= | Silent (SNP) | VAF 42/134 reads (31%) | catalogued as COSV60320816; called by muse, mutect2, varscan2
- CSMD1 | c.9462G>T p.V3154= (on ENST00000520002; = p.V3153= on NM_033225.6) | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV59288333; called by muse, mutect2, varscan2
- DMD | c.564C>T p.C188= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs751528345, CM148448, COSV55856454; called by muse, mutect2, varscan2
- FAM180A | c.382C>T p.L128= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV58527955; called by muse, mutect2, varscan2
- GPR12 | c.36G>T p.L12= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV67344097; called by muse, mutect2, varscan2
- GSC2 | c.573G>A p.A191= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV50082692; called by muse, mutect2, varscan2
- HBE1 | c.267G>A p.L89= | Silent (SNP) | VAF 35/139 reads (25%) | catalogued as COSV53079604; called by muse, mutect2, varscan2
- IPO11 | c.2775G>A p.K925= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV57572692; called by muse, mutect2, varscan2
- ITGA10 | c.1200G>A p.V400= | Silent (SNP) | VAF 35/135 reads (26%) | catalogued as COSV65196237; called by muse, mutect2, varscan2
- KCNT2 | c.1707G>A p.Q569= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV54066484, COSV99656079; called by muse, mutect2, varscan2
- KCNV2 | c.1335C>A p.P445= | Silent (SNP) | VAF 23/149 reads (15%) | catalogued as COSV101172565; called by muse, mutect2, varscan2
- KDM5D | c.3864G>A p.V1288= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV58736069; called by muse, mutect2, varscan2
- LRRC4B | c.1518G>A p.P506= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs1306297393, COSV65350723; called by muse, mutect2, varscan2
- MYO15A | c.369C>T p.R123= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs555850466, COSV52752711; called by muse, mutect2
- MYO7A | c.3615C>T p.S1205= | Silent (SNP) | VAF 8/182 reads (4%) | catalogued as rs782742557, COSV68683677; called by muse, mutect2
- NAXD | c.195T>A p.S65= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV59393706; called by muse, mutect2, varscan2
- NCKIPSD | c.771A>G p.Q257= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as COSV99583852; called by muse, mutect2, varscan2
- NDST4 | c.15G>A p.V5= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV52110496; called by muse, mutect2, varscan2
- NMUR2 | c.369G>C p.T123= | Silent (SNP) | VAF 62/181 reads (34%) | catalogued as COSV54917427; called by muse, mutect2, varscan2
- NOC4L | c.1356C>T p.A452= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs541204285, COSV100400071; called by muse, mutect2, varscan2
- NPY5R | c.558A>T p.T186= | Silent (SNP) | VAF 97/360 reads (27%) | catalogued as rs765193269, COSV58451167; called by muse, mutect2, varscan2
- NSD3 | c.2529C>T p.Y843= | Silent (SNP) | VAF 33/176 reads (19%) | catalogued as rs780717749, COSV57667309; called by muse, mutect2, varscan2
- OGDHL | c.265C>A p.R89= | Silent (SNP) | VAF 41/167 reads (25%) | catalogued as rs140510079, COSV65101223; called by muse, mutect2, varscan2
- OR10A3 | c.345G>A p.L115= | Silent (SNP) | VAF 60/158 reads (38%) | catalogued as COSV62459238; called by muse, mutect2, varscan2
- OR10C1 | c.354C>T p.A118= (on ENST00000622521; = p.A116= on NM_013941.3) | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as rs771580025, COSV65822328; called by muse, mutect2, varscan2
- OR14C36 | c.675G>T p.G225= | Silent (SNP) | VAF 9/126 reads (7%) | called by muse, mutect2
- OR2T27 | c.279C>A p.S93= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV100788202; called by mutect2, varscan2
- OR2T33 | c.444C>T p.L148= | Silent (SNP) | VAF 25/141 reads (18%) | catalogued as rs150467351; called by muse, mutect2, varscan2
- OR5L1 | c.153C>A p.V51= | Silent (SNP) | VAF 94/345 reads (27%) | catalogued as COSV61732967; called by muse, mutect2, varscan2
- PCDHA1 | c.1908C>G p.V636= | Silent (SNP) | VAF 50/149 reads (34%) | catalogued as rs146713367, COSV65372879; called by muse, mutect2, varscan2
- PDGFD | c.753C>T p.Y251= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV56369929; called by muse, mutect2, varscan2
- PIEZO2 | c.7956C>G p.V2652= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV53286843; called by muse, mutect2, varscan2
- PLAT | c.1461C>A p.T487= | Silent (SNP) | VAF 29/224 reads (13%) | catalogued as COSV54274377; called by muse, mutect2, varscan2
- PTPDC1 | c.1839A>T p.V613= (on ENST00000375360 / NM_177995.3; = p.V665= on NM_152422.4) | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs371377482, COSV56621827; called by muse, mutect2, varscan2
- PTPRF | c.4629C>T p.P1543= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- RAI1 | c.5007G>A p.T1669= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as rs765240763, COSV55389873; called by muse, mutect2, varscan2
- RBP3 | c.3739C>T p.L1247= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- RHOB | c.195C>T p.D65= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV99695202; called by muse, mutect2, varscan2
- SCN2A | c.5493A>T p.I1831= | Silent (SNP) | VAF 58/156 reads (37%) | catalogued as COSV51857690; called by muse, varscan2
- SIGLEC1 | c.4554G>T p.G1518= | Silent (SNP) | VAF 44/162 reads (27%) | catalogued as COSV52459434; called by muse, mutect2, varscan2
- SMARCA4 | c.4617C>T p.F1539= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV60788186, COSV60810906; called by muse, mutect2, varscan2
- SPTBN2 | c.1248G>A p.E416= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs775075151, COSV59447845; called by muse, mutect2, varscan2
- STAB2 | c.3993C>T p.V1331= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV101185863; called by muse, mutect2, varscan2
- THBS2 | c.426C>A p.V142= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as rs570537028, COSV64677295; called by muse, mutect2, varscan2
- TRIM40 | c.363G>A p.R121= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV57155977; called by muse, mutect2, varscan2
- TRPC4 | c.393C>A p.L131= | Silent (SNP) | VAF 42/162 reads (26%) | catalogued as rs547672368, COSV58991847; called by muse, mutect2, varscan2
- VEPH1 | c.798A>T p.P266= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as rs763945145, COSV62876424; called by muse, mutect2, varscan2
- VPS26B | c.93C>T p.D31= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as rs770630281, COSV55544265; called by muse, mutect2, varscan2
- WARS2 | c.1035A>G p.L345= | Silent (SNP) | VAF 56/203 reads (28%) | catalogued as COSV52476115; called by muse, mutect2, varscan2
- ZNF263 | c.1230C>T p.D410= | Silent (SNP) | VAF 43/173 reads (25%) | catalogued as rs993018733, COSV99526844; called by muse, mutect2, varscan2
- ZNF479 | c.1329C>A p.G443= | Silent (SNP) | VAF 33/148 reads (22%) | catalogued as COSV58636334; called by muse, mutect2, varscan2
- ZNF799 | c.1179C>T p.H393= | Silent (SNP) | VAF 67/183 reads (37%) | catalogued as rs781354071, COSV70122019; called by muse, mutect2, varscan2
- ABCA1 | c.720+2602C>G | Intron (SNP) | VAF 6/58 reads (10%) | catalogued as COSV101036797; called by muse, mutect2
- AL133467.6 | chr14:95671376 C>T | 3'Flank (SNP) | VAF 7/63 reads (11%) | catalogued as rs866267551; called by mutect2, varscan2
- AL136982.4 | n.1524G>A | RNA (SNP) | VAF 66/222 reads (30%) | called by muse, mutect2, varscan2
- ARMC5 | c.1864+243A>T | Intron (SNP) | VAF 22/103 reads (21%) | catalogued as COSV99192422; called by muse, mutect2, varscan2
- CPLANE1 | c.*4161A>T | 3'UTR (SNP) | VAF 6/90 reads (7%) | catalogued as COSV57053779; called by muse, mutect2
- DCHS2 | n.5282A>T | RNA (SNP) | VAF 37/169 reads (22%) | catalogued as COSV61768685; called by muse, mutect2, varscan2
- GBA3 | c.59-8224T>A | Intron (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- SLIT2 | c.1463-637A>C | Intron (SNP) | VAF 11/48 reads (23%) | catalogued as COSV56562120; called by muse, mutect2, varscan2
- VNN3 | c.*489C>A | 3'UTR (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99258215; called by muse, mutect2, varscan2
- ZC3H14 | c.1280-1755G>T | Intron (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99193007; called by muse, mutect2, varscan2
